Somatic mutation profile of tumor specimen TCGA-HC-8265-01B (aliquot TCGA-HC-8265-01B-04D-2298-08) from TCGA case TCGA-HC-8265, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,382 days).
Specimen TCGA-HC-8265-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 976c647f-cc32-4e9a-8b20-395cc43c8c18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8265-10A (Blood Derived Normal), aliquot TCGA-HC-8265-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3699830-21d5-43a4-bdd5-8288c161512d

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 26, Silent 13, Frame Shift Del 6, Nonsense Mutation 4, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- STAT3 | c.1414A>G p.N472D | Missense Mutation (SNP) | VAF 118/441 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1057520377, CM083168, COSV52885159; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF1 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV64799686; called by muse, mutect2, varscan2
- AGXT | c.682A>C p.K228Q | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV56753375, COSV56753759; called by muse, mutect2, varscan2
- C1QL4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as rs750966716, COSV57743425; called by muse, mutect2, varscan2
- CBLN1 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.529); catalogued as COSV54654218; called by muse, mutect2, varscan2
- CDK12 | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 226/825 reads (27%) | catalogued as COSV70999749, COSV99067788; called by muse, mutect2, varscan2
- CT45A10 | c.300C>A p.S100R | Missense Mutation (SNP) | VAF 159/294 reads (54%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.986); catalogued as COSV65921142; called by muse, mutect2, varscan2
- CYP4F2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs751855405, COSV55620541; called by muse, mutect2, varscan2
- CYP4F3 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs1216034192, COSV55412420; called by muse, mutect2, varscan2
- CYSLTR2 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 108/433 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV56165402; called by muse, mutect2, varscan2
- DDI1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs138983347, COSV56380960; called by muse, mutect2, varscan2
- DDIT4 | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56577203; called by muse, mutect2, varscan2
- FOXA1 | c.746A>T p.D249V | Missense Mutation (SNP) | VAF 131/228 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51644631, COSV51650069; called by muse, mutect2, varscan2
- IFT122 | c.3067C>T p.R1023C (on ENST00000348417 / NM_052989.3; = p.R964C on NM_018262.4) | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as rs761387325; called by muse, mutect2, varscan2
- IRAG1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs371956442; called by muse, mutect2, varscan2
- KIF20A | c.1000G>T p.D334Y | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50145987; called by muse, mutect2, varscan2
- LANCL1 | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 227/801 reads (28%) | catalogued as COSV52064486, COSV52066226; called by muse, mutect2, varscan2
- MDN1 | c.15638A>G p.K5213R | Missense Mutation (SNP) | VAF 92/277 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV65518838, COSV65523427; called by muse, mutect2, varscan2
- OBSCN | c.4541G>A p.C1514Y | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52752991; called by muse, mutect2, varscan2
- PCDH11X | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.078); catalogued as COSV53451571; called by muse, mutect2, varscan2
- PCDH15 | c.5059C>A p.P1687T (on ENST00000644397 / NM_001354429.2; = p.P1629T on NM_001142771.2) | Missense Mutation (SNP) | VAF 195/639 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.162); catalogued as rs762646821, COSV64680965; called by muse, mutect2, varscan2
- STAT1 | c.649A>C p.I217L | Missense Mutation (SNP) | VAF 86/267 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61189714; called by muse, mutect2, varscan2
- TMC1 | c.2212G>C p.A738P | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV52769779; called by muse, mutect2
- TOP2B | c.3662del p.G1221Afs*5 (on ENST00000264331 / NM_001330700.2; = p.G1216Afs*5 on NM_001068.3) | Frame Shift Del (DEL) | VAF 100/527 reads (19%) | catalogued as COSV51977176; called by mutect2, pindel, varscan2
- TTN | c.98697T>A p.Y32899* (on ENST00000591111; = p.Y25475* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 118/445 reads (27%) | catalogued as COSV59941353; called by muse, mutect2, varscan2
- ALG14 | c.70del p.V24* | Frame Shift Del (DEL) | VAF 140/663 reads (21%) | called by mutect2, pindel, varscan2
- ATG2A | c.1577dup p.W527Vfs*7 | Frame Shift Ins (INS) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- CD1B | c.328T>A p.Y110N | Missense Mutation (SNP) | VAF 165/905 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- CDK12 | c.163_178del p.L55Qfs*32 | Frame Shift Del (DEL) | VAF 77/340 reads (23%) | called by mutect2, pindel, varscan2
- CKM | c.481+1G>T p.X161_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- DMXL1 | c.6521dup p.S2175Vfs*28 | Frame Shift Ins (INS) | VAF 180/651 reads (28%) | called by mutect2, pindel, varscan2
- IGFALS | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MAGEC3 | c.814del p.Q272Rfs*5 | Frame Shift Del (DEL) | VAF 156/347 reads (45%) | called by mutect2, pindel, varscan2
- MYB | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 87/265 reads (33%) | called by muse, mutect2, varscan2
- MYH3 | c.4179dup p.L1394Tfs*13 | Frame Shift Ins (INS) | VAF 53/301 reads (18%) | called by mutect2, pindel, varscan2
- SEMA6A | c.1534del p.G513Afs*24 | Frame Shift Del (DEL) | VAF 103/482 reads (21%) | called by mutect2, pindel, varscan2
- SV2B | c.641G>C p.G214A | Missense Mutation (SNP) | VAF 130/501 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UTP15 | c.624_639del p.V209Ffs*22 | Frame Shift Del (DEL) | VAF 84/334 reads (25%) | called by mutect2, pindel, varscan2
- ZNHIT1 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 108/390 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- AKAP17A | c.903G>A p.A301= | Silent (SNP) | VAF 51/235 reads (22%) | catalogued as rs780856400; called by muse, mutect2, varscan2
- CCDC9 | c.1239G>T p.G413= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- JOSD2 | c.504C>T p.C168= | Silent (SNP) | VAF 60/206 reads (29%) | catalogued as rs770479330; called by muse, mutect2, varscan2
- KLHL14 | c.1323G>A p.V441= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- MYCN | c.978C>A p.I326= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- OR1A1 | c.234C>T p.I78= | Silent (SNP) | VAF 96/397 reads (24%) | called by muse, mutect2, varscan2
- POLR3D | c.399A>G p.G133= | Silent (SNP) | VAF 37/162 reads (23%) | catalogued as rs200322424, COSV60570742; called by muse, mutect2, varscan2
- PPARGC1A | c.1458C>T p.D486= | Silent (SNP) | VAF 114/384 reads (30%) | catalogued as COSV53525606, COSV53528274; called by muse, mutect2, varscan2
- SNX13 | c.1120C>T p.L374= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV68064207, COSV68065224; called by muse, mutect2, varscan2
- TMC1 | c.2214T>G p.A738= | Silent (SNP) | VAF 54/200 reads (27%) | catalogued as COSV52769796; called by muse, mutect2
- UBR7 | c.918C>T p.P306= | Silent (SNP) | VAF 61/325 reads (19%) | catalogued as rs754953234, COSV50151356; called by muse, mutect2, varscan2
- YLPM1 | c.2385C>T p.P795= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV53108304; called by muse, mutect2
- ZNF154 | c.657T>C p.C219= | Silent (SNP) | VAF 108/404 reads (27%) | catalogued as COSV70744839; called by muse, mutect2, varscan2
